Gene-level copy-number profile of tumor specimen TCGA-ZF-AA58-01A from TCGA case TCGA-ZF-AA58, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 61.7 years (22,549 days).
Specimen TCGA-ZF-AA58-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6fbc27ce-d6bc-4b7e-bf86-d3b870900c48.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-AA58-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a7a61127-95f2-42db-ba50-fc29501eb288

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,689; copy number 3: 10,395; copy number 4: 21,319; copy number 5: 11,292; copy number 6: 7,660; copy number 7: 3,145; copy number 8: 2,159; copy number 9: 78; copy number 10: 280; copy number 11: 508; copy number 13: 153; copy number 14: 1; copy number 16: 6; copy number 17: 67; copy number 27: 64; copy number 28: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-AA58-01A-12D-A42D-01): tumor purity 0.31, ploidy 2.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,159 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:54,456,317–54,671,446, 1 gene, copy number 9 (within-gene range 5–9): SPTBN1.
- chr2:54,661,011–54,680,045, 1 gene, copy number 9: AC093110.1.
- chr2:131,758,031–137,677,718, 77 genes, copy number 9–14 (within-gene range 4–14) (broad region; genes not listed).
- chr2:140,103,583–140,221,485, 4 genes, copy number 10: LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr2:140,234,737–140,992,659, 5 genes, copy number 10: AC092156.1, MIR7157, COPRSP1, LRRC57P1, Y_RNA.
- chr5:16,661,907–16,941,951, 4 genes, copy number 16 (within-gene range 6–16): MYO10, RNA5SP179, RPS26P28, RNU6-660P.
- chr5:17,107,360–17,117,686, 2 genes, copy number 16: AC026790.1, Y_RNA.
- chr8:93,698,561–103,501,895, 236 genes, copy number 10 (broad region; genes not listed).
- chr8:103,559,099–103,568,978, 2 genes, copy number 10: PTMAP15, AC007751.1.
- chr8:114,791,653–145,066,685, 508 genes, copy number 11 (broad region; genes not listed).
- chr16:82,688,931–82,689,019, 1 gene, copy number 10: MIR8058.
- chr19:23,897,321–28,429,490, 31 genes, copy number 10: AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1, ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1.
- chr19:28,437,060–28,535,277, 1 gene, copy number 10 (within-gene range 7–10): AC005381.1.
- chr19:30,553,956–30,668,647, 2 genes, copy number 28: AC011504.1, AC011478.1.
- chr19:33,997,289–39,385,710, 284 genes, copy number 13–27 (within-gene range 4–27) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
